Somatic mutation profile of tumor specimen TCGA-12-0688-01A (aliquot TCGA-12-0688-01A-02D-1492-08) from TCGA case TCGA-12-0688, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.2 years (27,085 days).
Specimen TCGA-12-0688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93c90f82-4ce3-4191-91dd-6a67261a253b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0688-10A (Blood Derived Normal), aliquot TCGA-12-0688-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/010427c5-94f5-4ba9-a77b-a480823733bd

The open-access MAF lists 59 somatic variants for this specimen: 36 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 20, Frame Shift Del 4, Nonsense Mutation 2, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1679A>G p.D560G (on ENST00000521381 / NM_181523.3; = p.D290G on NM_181504.4) | Missense Mutation (SNP) | VAF 54/144 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57125813; called by muse, mutect2, varscan2
- ATF7IP | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53769888; called by muse, mutect2, varscan2
- BRAT1 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346287649, COSV61395089; called by muse, mutect2, varscan2
- CBLB | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.062); catalogued as COSV51425449; called by muse, mutect2, varscan2
- CNTNAP2 | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs138661307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF13 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 63/90 reads (70%) | catalogued as COSV59544093; called by muse, mutect2, varscan2
- G6PC3 | c.418C>A p.R140S | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as COSV52243779; called by muse, mutect2
- GATA6 | c.1587T>A p.N529K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as COSV52525333; called by muse, mutect2, varscan2
- IRF4 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs781586995, COSV66705021, COSV66706054; called by muse, mutect2, varscan2
- KCNG1 | c.643G>C p.D215H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV65370402, COSV99056474; called by muse, mutect2, varscan2
- LPA | c.4190G>A p.R1397Q | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs199747804; called by muse, mutect2, varscan2
- METTL24 | c.1043A>C p.D348A | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58821916; called by muse, mutect2, varscan2
- MMP13 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV52823761; called by muse, mutect2, varscan2
- MS4A3 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV53935849; called by muse, mutect2, varscan2
- NFKBIE | c.982G>A p.D328N (on ENST00000275015; = p.D189N on NM_004556.3) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV51488881; called by muse, mutect2, varscan2
- NOTCH2 | c.467del p.G156Efs*240 | Frame Shift Del (DEL) | VAF 61/218 reads (28%) | catalogued as COSV56706555; called by mutect2, pindel, varscan2
- OR10C1 | c.193C>T p.R65C (on ENST00000622521; = p.R63C on NM_013941.3) | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs755057225, COSV65822205; called by muse, mutect2, varscan2
- OR14I1 | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV61199485; called by muse, mutect2, varscan2
- OR1L1 | c.421A>G p.T141A (on ENST00000373686; = p.T91A on NM_001005236.3) | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV58935514; called by muse, mutect2, varscan2
- OR2T3 | c.189del p.M64Cfs*18 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as COSV100613141; called by mutect2, varscan2
- PDE1C | c.103A>G p.R35G | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1223453618, COSV58511909; called by muse, mutect2, varscan2
- PDHA2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs550119402, COSV54777272; called by muse, mutect2, varscan2
- PHLDB2 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1287508953, COSV67310596; called by muse, mutect2, varscan2
- PXDNL | c.2710G>T p.E904* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as rs1385692259, COSV62482337, COSV62486113; called by muse, mutect2, varscan2
- RALBP1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV50035031; called by muse, mutect2, varscan2
- SBNO2 | c.2234A>G p.Q745R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV62318624, COSV62320204; called by muse, mutect2, varscan2
- SP4 | c.2339A>G p.N780S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.332); catalogued as rs1368031304, COSV56022267; called by muse, mutect2, varscan2
- SPATA31A3 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554911040; called by muse, mutect2, varscan2
- STAP1 | c.644T>C p.I215T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as COSV55330309; called by muse, mutect2, varscan2
- SYNE2 | c.16753C>T p.R5585C | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs370674900, COSV59946696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIGD5 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55309085; called by muse, mutect2
- TRPM3 | c.1075G>A p.V359M (on ENST00000357533 / NM_001366142.2; = p.V204M on NM_020952.6) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs141951214; called by muse, mutect2, varscan2
- VRK2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs139700760; called by muse, mutect2
- ZNF554 | c.679A>T p.N227Y | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV57885316; called by muse, mutect2, varscan2
- OR2T34 | c.189del p.M64Cfs*18 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- PTPN2 | c.1053del p.K351Nfs*18 | Frame Shift Del (DEL) | VAF 38/130 reads (29%) | called by pindel, varscan2
- ASL | c.1029C>G p.L343= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs140532520, COSV59188354; called by muse, mutect2, varscan2
- CDH2 | c.414T>G p.V138= | Silent (SNP) | VAF 78/192 reads (41%) | catalogued as COSV52278612; called by muse, mutect2, varscan2
- CLEC4M | c.1029C>T p.D343= | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as rs370711365; called by muse, mutect2, varscan2
- COL6A2 | c.642C>T p.N214= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs781584161, COSV56003660; called by muse, mutect2
- EFCC1 | c.1599G>A p.S533= | Silent (SNP) | VAF 67/201 reads (33%) | catalogued as rs575259155, COSV71401820; called by muse, mutect2, varscan2
- EGF | c.2572T>C p.L858= | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as rs758145480, COSV54478028; called by muse, mutect2, varscan2
- EXD3 | c.2613G>A p.P871= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs773823557, COSV59806597; called by muse, mutect2, varscan2
- FAM83B | c.2322G>A p.K774= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV60921565; called by muse, mutect2, varscan2
- FAM83H | c.2826C>T p.S942= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs544120916, COSV62028085; called by muse, mutect2, varscan2
- FGFBP2 | c.438G>A p.G146= | Silent (SNP) | VAF 84/255 reads (33%) | catalogued as COSV52587864; called by muse, mutect2, varscan2
- FLT4 | c.1959C>T p.C653= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs373635248; called by muse, mutect2, varscan2
- GPRC5A | c.216C>T p.L72= | Silent (SNP) | VAF 129/318 reads (41%) | catalogued as COSV50007606; called by muse, mutect2, varscan2
- IVL | c.1671A>C p.P557= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV64216100; called by muse, mutect2, varscan2
- MCOLN1 | c.444G>A p.A148= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as rs374412302; called by muse, mutect2, varscan2
- NRROS | c.1575C>T p.S525= | Silent (SNP) | VAF 139/344 reads (40%) | catalogued as COSV60745637; called by muse, mutect2, varscan2
- PADI6 | c.267G>A p.S89= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs752925449, COSV61885683; called by muse, mutect2, varscan2
- RPN2 | c.825T>C p.P275= | Silent (SNP) | VAF 99/396 reads (25%) | catalogued as COSV52905207; called by muse, mutect2, varscan2
- SLC13A3 | c.1425C>T p.I475= | Silent (SNP) | VAF 96/348 reads (28%) | catalogued as rs147641404, COSV51714483; called by muse, varscan2
- WDR72 | c.2985G>A p.A995= | Silent (SNP) | VAF 112/299 reads (37%) | catalogued as rs745403939, COSV64745745; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF816 | c.1728A>G p.Q576= | Silent (SNP) | VAF 64/217 reads (29%) | catalogued as COSV54411050; called by muse, mutect2, varscan2
- ACYP1 | c.84+1786G>T | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as COSV53134886; called by muse, mutect2, varscan2
- CAMKK2 | c.-214C>T | 5'UTR (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100242586; called by muse, mutect2, varscan2
- TECR | chr19:14529563 G>T | 5'Flank (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99295421; called by muse, mutect2, varscan2
